Surgical pathology report (de-identified scan), TCGA case TCGA-91-7771, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ABS - IUPUI, specimen TCGA-91-7771-01A (Primary Tumor).

[page 1 of 3]
Final Pathologic Diagnosis:

A. Mediastinal mass, resection:

Thymoma, type A.

1.6 cm in the largest dimension.

Completely excised.

B. Lymph node, 11R, resection:

No evidence of malignancy (1 lymph node).

C. Lung, right upper lobe, resection:

Specimen: Lung; Lobe of lung (specify): right upper lobe

Procedure: Lobectomy

Specimen laterality: right

Tumor site: right upper lobe

Specimen integrity: previously incised, but intact

Tumor size: 8.3 cm (greatest dimension)

Tumor focality: Unifocal

Tumor histologic type: Adenocarcinoma

Tumor grade: well differentiated

Visceral pleura invasion: Not identified.

Tumor extension: Not identified

Margins:

Bronchial margin: Uninvolved by invasive carcinoma

Vascular margin: Uninvolved by invasive carcinoma

Parenchymal margin: Uninvolved by invasive carcinoma

Parietal pleural margin: Uninvolved by invasive carcinoma

Chest wall margin: Not applicable

Other attached tissue margin: Not applicable

If all margins uninvolved by invasive carcinoma:

Distance of invasive carcinoma from closest margin: 1 mm

Specify margin: Parietal pleural margin

Treatment effect: Not

Lymph-vascular invasion: not present

Pathologic Staging (pTNM):

TNM Descriptors: none

Primary tumor (pT): pT3

Regional lymph nodes (pN): pN0

Number examined: 24

Number involved: 0

If lymph node(s) involved, specify involved nodal station(s): NA

Distant metastasis (pM): Not applicable

Additional pathologic findings: Focal emphysematous changes

D. Lymph node, 9R, inferior pulmonary ligament, resection:

No evidence of malignancy (3 lymph node).

E. 7R lymph nodes, resection:

No evidence of malignancy (8 lymph nodes).

[page 2 of 3]
F. 4R lymph nodes, resection:
No evidence of malignancy (13 lymph nodes).
Calcifying hyalinized granuloma.
No evidence of malignancy.

Note:

Intraoperative Consult Diagnosis:

FSA: Mediastinal mass:

Thymic tissue with spindle cell neoplastic proliferation. No metastatic adenocarcinoma identified. Wait for permanent sections for further clarification.

Gross Description:

The specimen is received in six parts, all labeled with the patient's name.

Part A is received fresh for frozen section diagnosis additionally labeled "mediastinal mass" and consists of a 5.3 x 2.6 x 0.7 cm portion of yellow-tan fatty tissue. Sectioning reveals a cystic like structure with a granular wall that is 3 x 2 x 1 cm and is does not contain any fluid. The remaining portion of tissue has a yellow-tan lobulated smooth and glistening cut surface. Residual frozen tissue is submitted in cassette A1. Other representative sections are submitted in cassettes A2-3.

Part B is received in a single formalin filled container additionally labeled "11R" and consists of a 2.1 x 1.8 x 1.4 cm red-brown irregular portion of soft tissue. The specimen is serially sectioned and submitted entirely in cassettes B1-2.

Part C is received fresh for collection by the Tissue Bank and. It is additionally labeled "right upper lobe" and consists of a previously incised lung lobe that is 17 x 7 x 3.5 cm. There is additionally, another portion of lung tissue in the same container that is 7 x 3 x 0.7 cm, which most likely came from the area previously incised on the larger portion. There is an 8.3 x 3.5 x 3.5 cm white-tan irregular, partially necrotic mass where the previous incision has been made. This lesion abuts the pleural surface in this area and is 2 cm from the nearest bronchial and vascular margin. The nearest lung parenchymal margin is 1.6 cm from the lesion. Further sectioning of the mass reveals a white to yellow-tan, multiloculated, partially hemorrhagic and necrotic mass. The mass appears to be involving the pleura, but not penetrating completely through the pleura.

Representative sections are submitted as follows:

- C1 bronchial and vascular margins;
- C2-3 mass to include overlying pleura;
- C4-5 mass to include adjacent lung parenchyma;
- C6 uninvolved lung parenchyma.

Part D is received in a single formalin filled container additionally labeled "9R; inferior pulmonary ligament" and consists of a 1.5 x 0.6 x 0.4 cm portion of lymph node with attached fibrous tissue. The specimen is bisected and entirely submitted in cassette D1.

[page 3 of 3]
Part E is received in a single formalin filled container additionally labeled "7R" and consists of multiple portions of irregular nodal tissue admixed with fibrous tissue, ranging from 1.5 to 0.4 cm in greatest dimension. The specimen is submitted in toto in cassettes E1-2.

Part F is received in a single formalin filled container additionally labeled "4R" and consists of two portions of fibrofatty soft tissue that are 4.0 x 1.3 x 0.5 cm and 2.6 x 1.2 x 0.9 cm. Multiple lymph nodes are identified, ranging from 0.3 to 1.0 cm.

Representative sections are submitted as follows:

- F1 multiple whole lymph nodes;
- F2 one lymph node bisected;
- F3 one lymph node bisected;
- F4 one lymph node bisected;
- F5 residual tissue for further lymph node capture.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

Taken: [REDACTED]

END OF REPORT

Source: NCI Genomic Data Commons file e095104a-7888-4ad9-a92c-5c44b5136bb0 (TCGA-91-7771.A8247167-A991-441B-B60A-9F69F4C5D9DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).